CCDI case PBCFPT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f745fc4b-1faa-4059-b6bf-3238f3f09849

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.9 years (7,268 days).

Biospecimens (3 samples)
- Sample 0DR536: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR53C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR53I: Tissue type: Tumor; Specimen type: Solid Tissue.
